Somatic mutation profile of tumor specimen 0DS6L8 from CCDI case PBCHRJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pleomorphic xanthoastrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,114 days).
Specimen 0DS6L8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9512af5-b0f7-4d0d-904b-fb75f00e6dc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS6LM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5a3f200-6710-4e5a-971d-78a7f66ea8f0

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Splice Site 2, Missense Mutation 2, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/370 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BTBD17 | c.1187C>A p.T396K | Missense Mutation (SNP) | VAF 117/408 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GCAT | c.731+2T>A p.X244_splice | Splice Site (SNP) | VAF 187/657 reads (28%) | called by muse, mutect2, varscan2
- JCHAIN | c.64+1del p.X22_splice | Splice Site (DEL) | VAF 77/310 reads (25%) | called by mutect2, pindel, varscan2
- ATP10B | c.1452C>G p.S484= | Silent (SNP) | VAF 124/490 reads (25%) | called by muse, mutect2, varscan2
- GABRA1 | c.510G>A p.L170= | Silent (SNP) | VAF 105/446 reads (24%) | called by muse, mutect2, varscan2
- GRM1 | c.2013C>T p.C671= | Silent (SNP) | VAF 20/398 reads (5%) | catalogued as COSV51120557; called by muse, mutect2
- CORO7 | c.*58C>T | 3'UTR (SNP) | VAF 74/268 reads (28%) | catalogued as rs769217875; called by muse, mutect2, varscan2
- FOXP2 | c.1094+60C>T | Intron (SNP) | VAF 17/394 reads (4%) | catalogued as rs1056496576; called by muse, mutect2
